Somatic mutation profile of tumor specimen CDDP-ACLV-TTP1-A (aliquot CDDP-ACLV-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACLV, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76 years.
Specimen CDDP-ACLV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7ab8ff5-17bd-4a42-b2f1-1f4ba67a1744.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACLV-NB1-A (Blood Derived Normal), aliquot CDDP-ACLV-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a0ded14-7360-4687-9c1a-a30a6db6d02a

The open-access MAF lists 276 somatic variants for this specimen: 198 protein-altering or splice-affecting, 49 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 49, Nonsense Mutation 15, Intron 11, 5'Flank 6, Frame Shift Del 5, 3'UTR 5, 3'Flank 4, Splice Site 3, RNA 3, Frame Shift Ins 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 356/478 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 207/519 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV55949514; called by muse, mutect2, varscan2
- ABCA8 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV52194416; called by muse, mutect2, varscan2
- ABCB5 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs372984477; called by muse, mutect2, varscan2
- ABCC3 | c.1737A>T p.R579S | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV53317316; called by muse, mutect2, varscan2
- ABI3BP | c.2057T>A p.V686E | Missense Mutation (SNP) | VAF 104/297 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1392720313, COSV52528490; called by muse, mutect2, varscan2
- ACACB | c.5669G>T p.R1890I | Missense Mutation (SNP) | VAF 178/265 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58141141; called by muse, mutect2, varscan2
- ACMSD | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV51605373; called by muse, mutect2
- ACTRT2 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65758853; called by muse, mutect2, varscan2
- ADAM8 | c.1889A>T p.H630L | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV69864313; called by muse, mutect2, varscan2
- ADGRL4 | c.119A>C p.E40A | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV66059324; called by muse, mutect2, varscan2
- AL592490.1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as COSV69424569; called by muse, mutect2, varscan2
- ANKK1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as COSV58270349; called by muse, mutect2, varscan2
- ANKRD17 | c.1472C>G p.A491G | Missense Mutation (SNP) | VAF 171/406 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58215534; called by muse, mutect2, varscan2
- APBB1IP | c.1936G>T p.G646W | Missense Mutation (SNP) | VAF 102/452 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1267394352, COSV66130561; called by muse, mutect2, varscan2
- ARHGAP25 | c.847C>G p.R283G (on ENST00000409202 / NM_001007231.3; = p.R275G on NM_014882.3) | Missense Mutation (SNP) | VAF 121/377 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54898396; called by muse, mutect2, varscan2
- BAG1 | c.1018A>C p.N340H | Missense Mutation (SNP) | VAF 105/274 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV65651433; called by muse, mutect2, varscan2
- BMPR1B | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as COSV52774805; called by muse, mutect2, varscan2
- BRWD3 | c.1462G>T p.G488W | Missense Mutation (SNP) | VAF 142/210 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64743992; called by muse, mutect2, varscan2
- BUB1 | c.1416G>T p.M472I | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57061284, COSV57062328; called by muse, mutect2, varscan2
- C2orf72 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV65378353; called by muse, mutect2, varscan2
- C4orf54 | c.2425G>T p.A809S | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs760940167; called by muse, mutect2, varscan2
- C9orf43 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55911819; called by muse, mutect2, varscan2
- CACNA1C | c.1999C>A p.L667I | Missense Mutation (SNP) | VAF 169/260 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59697345; called by muse, mutect2, varscan2
- CALCRL | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV66473507, COSV66476306; called by muse, mutect2, varscan2
- CCDC146 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs552375827, COSV53544047, COSV99035595; called by muse, mutect2, varscan2
- CD34 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV60411734; called by muse, mutect2, varscan2
- CEP44 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV56658457; called by muse, mutect2, varscan2
- CFAP58 | c.2582del p.G861Afs*10 | Frame Shift Del (DEL) | VAF 40/296 reads (14%) | catalogued as COSV100866132; called by mutect2, pindel, varscan2
- CHRND | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 146/392 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV51317399; called by muse, mutect2, varscan2
- CLCN1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 146/475 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763850295, COSV58367435; ClinVar: likely benign; called by muse, mutect2, varscan2
- CR1 | c.4748C>T p.P1583L | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544740223, COSV65462344; called by muse, mutect2, varscan2
- CSNK1A1L | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as COSV65789355, COSV65789942; called by muse, mutect2, varscan2
- CTNNBL1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV63743685, COSV63744421; called by muse, mutect2, varscan2
- CTTNBP2 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs776855094, COSV99353984; called by muse, mutect2, varscan2
- DENND6B | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV69806598, COSV69806979; called by muse, mutect2, varscan2
- DNAJC16 | c.1715A>T p.E572V | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65448078; called by muse, mutect2, varscan2
- DUOX1 | c.4382T>C p.F1461S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52049339; called by muse, mutect2, varscan2
- EMILIN3 | c.1496C>A p.A499D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV60035129; called by muse, mutect2
- EML6 | c.5237G>A p.G1746D | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62863281; called by muse, varscan2
- ERRFI1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV66310301; called by muse, mutect2, varscan2
- F2 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.718); catalogued as COSV61314741, COSV61315594; called by muse, mutect2, varscan2
- FAM135B | c.3149A>T p.E1050V | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV52705719; called by muse, mutect2, varscan2
- FANCM | c.3622G>T p.G1208C | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV57497409; called by muse, mutect2, varscan2
- FAT4 | c.6127G>T p.D2043Y | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627214, COSV58671970; called by muse, mutect2, varscan2
- FCRLA | c.674C>A p.A225D (on ENST00000367959; = p.A202D on NM_032738.4) | Missense Mutation (SNP) | VAF 94/625 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV52684361; called by muse, mutect2, varscan2
- FMN2 | c.4584T>C p.S1528= | Splice Region (SNP) | VAF 48/148 reads (32%) | catalogued as COSV60417277; called by muse, mutect2, varscan2
- FRAS1 | c.6374G>T p.G2125V | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53589657; called by muse, mutect2, varscan2
- GABPB1 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 74/270 reads (27%) | catalogued as COSV55013694; called by muse, mutect2, varscan2
- GABRD | c.1352C>A p.A451D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV66079855; called by muse, mutect2, varscan2
- GK2 | c.1406T>A p.V469E | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV62626133; called by muse, mutect2, varscan2
- GLB1L2 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV60277386; called by muse, mutect2, varscan2
- GPR161 | c.1015T>C p.C339R | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54787742; called by muse, mutect2, varscan2
- HCRTR2 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 90/514 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100904510, COSV63793838; called by muse, mutect2, varscan2
- HEPH | c.229A>G p.I77V (on ENST00000343002; = p.I131V on NM_138737.5) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369897547, COSV57959068; called by muse, mutect2, varscan2
- HGFAC | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1560192184; called by muse, mutect2, varscan2
- HMCN1 | c.16382A>C p.Y5461S | Missense Mutation (SNP) | VAF 69/459 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54877867; called by muse, mutect2, varscan2
- HS3ST4 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs578031781, COSV58802034; called by muse, mutect2, varscan2
- HSD3B1 | c.933T>G p.Y311* | Nonsense Mutation (SNP) | VAF 56/93 reads (60%) | catalogued as COSV52489570; called by muse, mutect2, varscan2
- IRX4 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 129/1346 reads (10%) | catalogued as COSV51470619, COSV51470842; called by muse, mutect2
- JMJD1C | c.3858A>T p.K1286N | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV59512782; called by muse, mutect2, varscan2
- KCNH4 | c.2957C>A p.P986H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV52915373; called by muse, mutect2, varscan2
- KCNT2 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 141/286 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV54064666, COSV54109464; called by muse, mutect2, varscan2
- KIF17 | c.2220G>C p.Q740H | Missense Mutation (SNP) | VAF 132/307 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV56115762; called by muse, mutect2, varscan2
- KLF1 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV53434457; called by muse, mutect2, varscan2
- KLHDC3 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as COSV55063605; called by muse, mutect2, varscan2
- KMT2D | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as COSV56411498; called by muse, mutect2, varscan2
- KMT2D | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 207/558 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV56411515, COSV56495976; called by muse, mutect2, varscan2
- KMT2D | c.3016G>A p.G1006S | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV56411535; called by muse, mutect2, varscan2
- KRIT1 | c.2023A>G p.K675E | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60666840; called by muse, mutect2, varscan2
- LAMA2 | c.1478A>T p.E493V | Missense Mutation (SNP) | VAF 84/451 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70338824; called by muse, mutect2, varscan2
- LAMA3 | c.4928del p.G1643Efs*5 | Frame Shift Del (DEL) | VAF 62/152 reads (41%) | catalogued as COSV99334839; called by mutect2, pindel, varscan2
- LPA | c.4531C>G p.R1511G | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60296889, COSV60306904; called by muse, mutect2, varscan2
- LRRC36 | c.1534G>T p.G512* | Nonsense Mutation (SNP) | VAF 107/229 reads (47%) | catalogued as COSV52078137; called by muse, mutect2, varscan2
- LRRN2 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs371687072; called by muse, mutect2, varscan2
- LVRN | c.2431G>T p.V811L | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs778696086, COSV63495991; called by muse, mutect2, varscan2
- MAST2 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV63616153; called by muse, mutect2, varscan2
- MCTP2 | c.1873G>C p.D625H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV59140877; called by muse, mutect2, varscan2
- MEGF10 | c.1050C>G p.C350W | Missense Mutation (SNP) | VAF 74/542 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57245096; called by muse, mutect2, varscan2
- MLF2 | c.466C>G p.H156D | Missense Mutation (SNP) | VAF 249/306 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52570626; called by muse, mutect2, varscan2
- MMP20 | c.436T>A p.L146M | Missense Mutation (SNP) | VAF 115/254 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV52773923; called by muse, mutect2, varscan2
- MS4A14 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 81/415 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV55733133; called by muse, mutect2, varscan2
- MS4A3 | c.521T>A p.V174E | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53934825; called by muse, mutect2, varscan2
- MTBP | c.1110A>T p.Q370H | Missense Mutation (SNP) | VAF 185/462 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59960991; called by muse, mutect2, varscan2
- MUC12 | c.2209G>A p.D737N (on ENST00000379442; = p.D594N on NM_001164462.1) | Missense Mutation (SNP) | VAF 98/618 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); catalogued as COSV65183877; called by mutect2, varscan2
- MYO7B | c.5164T>C p.S1722P | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV67344561; called by muse, mutect2, varscan2
- MYT1L | c.2449T>A p.L817M | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as COSV67708594; called by muse, mutect2, varscan2
- NANOG | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 282/491 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.312); catalogued as COSV57550906; called by muse, mutect2, varscan2
- NAV3 | c.2246C>G p.P749R | Missense Mutation (SNP) | VAF 118/182 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749764974, COSV57062385; called by muse, mutect2, varscan2
- NEB | c.1766C>A p.T589N | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as COSV50811700; called by muse, mutect2, varscan2
- NFATC1 | c.2444G>T p.G815V | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV53695289; called by muse, mutect2, varscan2
- NLRP3 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 77/130 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60220096; called by muse, mutect2, varscan2
- NRG1 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750264919, COSV55168583; called by muse, mutect2, varscan2
- NXPE1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 64/167 reads (38%) | catalogued as rs1468031473; called by muse, mutect2, varscan2
- OR10AG1 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV56631488; called by muse, mutect2, varscan2
- OR1J2 | c.904G>T p.G302W | Missense Mutation (SNP) | VAF 121/420 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV58943727; called by muse, mutect2, varscan2
- OR2F2 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs376743624, COSV101283801; called by muse, mutect2, varscan2
- OR4Q2 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 121/437 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373937732; called by muse, mutect2, varscan2
- OR9G4 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV57247682; called by muse, mutect2, varscan2
- OR9Q2 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV61111377; called by muse, mutect2, varscan2
- PA2G4 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 254/740 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57567456; called by muse, mutect2, varscan2
- PAN2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 137/191 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as COSV57752717; called by muse, varscan2
- PARP14 | c.4667T>G p.L1556* | Nonsense Mutation (SNP) | VAF 68/177 reads (38%) | catalogued as COSV71734116; called by muse, mutect2, varscan2
- PCDHGA1 | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); catalogued as COSV65294958, COSV65300482; called by muse, mutect2, varscan2
- PDE10A | c.2170C>A p.Q724K | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1256280186, COSV63091209; called by muse, mutect2, varscan2
- PDIA5 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60247164, COSV60252757; called by muse, varscan2
- PGR | c.2307A>T p.K769N | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54796302; called by muse, mutect2, varscan2
- PLCB3 | c.420G>T p.M140I | Missense Mutation (SNP) | VAF 121/310 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV54185904; called by muse, mutect2, varscan2
- PRKN | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as rs749768565, COSV100627580, COSV58224511; called by muse, mutect2, varscan2
- PRR33 | c.246C>A p.H82Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs771070839; called by muse, mutect2, varscan2
- PRTG | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66836796, COSV66837991; called by muse, mutect2, varscan2
- PTS | c.160A>G p.K54E | Missense Mutation (SNP) | VAF 158/392 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV54785297; called by muse, mutect2, varscan2
- RASGRP3 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 71/247 reads (29%) | catalogued as COSV101274675, COSV67820431; called by muse, mutect2, varscan2
- RBMS2 | c.647A>G p.K216R | Missense Mutation (SNP) | VAF 174/376 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.544); catalogued as rs575794871, COSV56262877; called by muse, mutect2, varscan2
- RGS18 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 66/181 reads (36%) | catalogued as COSV66507132; called by muse, mutect2, varscan2
- RGS7 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 216/712 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV58531038, COSV58536186; called by muse, mutect2, varscan2
- RNASE6 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV58977277; called by muse, mutect2, varscan2
- SEMA6C | c.856A>G p.N286D | Missense Mutation (SNP) | VAF 165/884 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59000045; called by muse, mutect2, varscan2
- SEMA6D | c.2951C>A p.P984Q (on ENST00000316364 / NM_153618.2; = p.P922Q on NM_020858.2) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60372910; called by muse, mutect2, varscan2
- SERGEF | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs185654092; called by muse, mutect2, varscan2
- SFI1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as COSV66289702; called by muse, mutect2, varscan2
- SI | c.4771C>A p.P1591T | Missense Mutation (SNP) | VAF 118/383 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52266293; called by muse, mutect2, varscan2
- SMYD1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV70224589; called by muse, mutect2, varscan2
- SNX6 | c.193A>C p.K65Q (on ENST00000652385; = p.K53Q on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/263 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV61917655; called by muse, varscan2
- SOD3 | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 157/404 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV66125462; called by muse, mutect2, varscan2
- SORCS3 | c.3629G>A p.S1210N | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs1267842801, COSV63802946; called by muse, mutect2, varscan2
- SPAG6 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV57618091; called by muse, mutect2, varscan2
- SPATA21 | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59185256; called by muse, mutect2, varscan2
- SPTA1 | c.2087C>A p.A696E | Missense Mutation (SNP) | VAF 323/546 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV63749068; called by muse, mutect2, varscan2
- STAMBP | c.663T>A p.C221* | Nonsense Mutation (SNP) | VAF 103/304 reads (34%) | catalogued as COSV59896877; called by muse, mutect2, varscan2
- STK11 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 138/223 reads (62%) | catalogued as CM991153, COSV58820162, COSV58820447; called by muse, mutect2, varscan2
- SUGCT | c.1263G>T p.R421S (on ENST00000335693 / NM_001193313.2; = p.R447S on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59314446, COSV59358223; called by muse, mutect2, varscan2
- TECPR1 | c.2152G>T p.E718* | Nonsense Mutation (SNP) | VAF 124/372 reads (33%) | catalogued as COSV65782582; called by muse, mutect2, varscan2
- THAP3 | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs751504961, COSV50010516; called by muse, mutect2, varscan2
- THSD7A | c.1433G>T p.S478I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV70260393; called by muse, mutect2, varscan2
- TMEM132A | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50000911; called by muse, mutect2, varscan2
- TOGARAM2 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65421255; called by muse, mutect2
- TRAPPC5 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs868647573, COSV58039454; called by muse, mutect2, varscan2
- TRIM64C | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 107/538 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1219419645; called by muse, mutect2, varscan2
- TSPYL5 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59070974; called by muse, mutect2, varscan2
- TTN | c.71080G>A p.E23694K (on ENST00000591111; = p.E16270K on NM_003319.4) | Missense Mutation (SNP) | VAF 76/240 reads (32%) | PolyPhen benign (0.318); catalogued as COSV59876542; called by muse, mutect2, varscan2
- UBR3 | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV55844624; called by muse, mutect2, varscan2
- USH1G | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58880652; called by muse, mutect2, varscan2
- USP28 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 160/437 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV50155796; called by muse, mutect2, varscan2
- VWA5B1 | c.2627-1G>A p.X876_splice | Splice Site (SNP) | VAF 47/289 reads (16%) | catalogued as COSV57060137; called by muse, mutect2, varscan2
- WDR37 | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 98/173 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54127022; called by muse, mutect2, varscan2
- WDR87 | c.7016G>A p.R2339K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58193241; called by mutect2, varscan2
- WNK3 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV63612130; called by muse, mutect2, varscan2
- ZFAND2B | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54692912; called by muse, mutect2, varscan2
- ZNF831 | c.1175C>A p.A392E | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756694854, COSV64037437; called by muse, mutect2, varscan2
- ZNF862 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 197/558 reads (35%) | catalogued as COSV56222749; called by muse, mutect2, varscan2
- ZSCAN5C | c.480C>G p.H160Q | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs187699193, COSV66186583; called by muse, mutect2, varscan2
- ZSWIM3 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1049775551; called by muse, mutect2, varscan2
- ACACB | c.5669+1G>T p.X1890_splice | Splice Site (SNP) | VAF 174/259 reads (67%) | called by muse, mutect2, varscan2
- ARL13B | c.631C>A p.L211I (on ENST00000394222 / NM_001174150.2; = p.L104I on NM_144996.4) | Missense Mutation (SNP) | VAF 25/371 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2
- ATM | c.7513A>T p.K2505* | Nonsense Mutation (SNP) | VAF 40/474 reads (8%) | called by muse, mutect2
- BMP2K | c.2362C>T p.L788F | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BNC2 | c.2422T>A p.F808I | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BTBD9 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CELA3B | c.363-2del p.X121_splice | Splice Site (DEL) | VAF 36/82 reads (44%) | called by mutect2, varscan2
- CLIC2 | c.635T>A p.V212D | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACR2A | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 22/409 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYP2A13 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 99/394 reads (25%) | called by muse, mutect2, varscan2
- CYP4F8 | c.1315-4C>A | Splice Region (SNP) | VAF 118/177 reads (67%) | called by muse, mutect2, varscan2
- ERMP1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FOXG1 | c.909dup p.G304Rfs*151 | Frame Shift Ins (INS) | VAF 76/220 reads (35%) | called by mutect2, pindel
- FYCO1 | c.1957del p.E653Nfs*32 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- GPBP1 | c.818dup p.N273Kfs*7 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- GPX5 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- HMCN1 | c.12377G>T p.R4126L | Missense Mutation (SNP) | VAF 342/534 reads (64%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- IGHV1-45 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- KIF19 | c.2948C>A p.P983H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- LRRC9 | c.4322T>A p.L1441Q | Missense Mutation (SNP) | VAF 130/388 reads (34%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEH1 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAN1C1 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 84/350 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MDM4 | c.1329A>T p.R443S | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC17 | c.12697_12700delinsTTTTTC p.V4233Ffs*4 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | called by pindel, varscan2*
- MUC2 | c.4046A>T p.E1349V | Missense Mutation (SNP) | VAF 123/323 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MYBPC3 | c.2721G>T p.E907D | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN4X | c.1172C>G p.T391R | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NUF2 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 24/439 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- ORC4 | c.932T>A p.M311K | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PIK3C2G | c.2743T>A p.C915S (on ENST00000676171; = p.C874S on NM_004570.5) | Missense Mutation (SNP) | VAF 21/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SFTA2 | c.101T>C p.F34S | Missense Mutation (SNP) | VAF 99/241 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SND1 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 58/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SPDYE5 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 94/376 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SPRY3 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ST8SIA6 | c.884del p.K295Rfs*10 | Frame Shift Del (DEL) | VAF 87/250 reads (35%) | called by mutect2, pindel, varscan2
- TAMM41 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TGFBI | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- TNPO3 | c.2749G>C p.D917H | Missense Mutation (SNP) | VAF 44/538 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); called by muse, mutect2
- TRAF3 | c.1365_1366del p.A456Qfs*27 | Frame Shift Del (DEL) | VAF 86/330 reads (26%) | called by pindel, varscan2
- TRAV41 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- UBASH3A | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZFP92 | c.1227G>T p.R409S | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF658 | c.2062T>A p.C688S | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF675 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 148/263 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ZSCAN4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADAMDEC1 | c.414C>T p.A138= | Silent (SNP) | VAF 68/156 reads (44%) | catalogued as COSV56474077; called by muse, mutect2, varscan2
- ARSK | c.207C>T p.S69= | Silent (SNP) | VAF 164/445 reads (37%) | catalogued as COSV66169235; called by muse, mutect2, varscan2
- C16orf92 | c.372C>G p.T124= | Silent (SNP) | VAF 67/228 reads (29%) | catalogued as COSV54226195; called by muse, mutect2, varscan2
- C2CD2 | c.24G>T p.S8= | Silent (SNP) | VAF 54/238 reads (23%) | catalogued as COSV66853634; called by muse, mutect2, varscan2
- CCDC168 | c.20169T>C p.H6723= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs1257802988, COSV59418783; called by muse, mutect2, varscan2
- CNTNAP3 | c.2943G>T p.G981= | Silent (SNP) | VAF 47/253 reads (19%) | catalogued as rs148834827; called by muse, mutect2, varscan2
- COG4 | c.2022C>T p.V674= | Silent (SNP) | VAF 142/317 reads (45%) | catalogued as COSV55367668; called by muse, mutect2, varscan2
- CSMD1 | c.6891C>T p.D2297= (on ENST00000520002; = p.D2296= on NM_033225.6) | Silent (SNP) | VAF 65/134 reads (49%) | catalogued as COSV59282762; called by muse, mutect2, varscan2
- DEFB119 | c.141C>A p.L47= | Silent (SNP) | VAF 79/314 reads (25%) | catalogued as COSV53619649; called by muse, mutect2, varscan2
- DGKI | c.291G>T p.A97= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as COSV55936863; called by muse, mutect2, varscan2
- DNAJC10 | c.2358C>G p.G786= | Silent (SNP) | VAF 97/323 reads (30%) | catalogued as COSV51135815; called by muse, mutect2, varscan2
- DOCK5 | c.876C>T p.P292= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, varscan2
- EIF4E1B | c.108A>T p.P36= | Silent (SNP) | VAF 92/410 reads (22%) | catalogued as COSV53779204; called by muse, mutect2, varscan2
- FRAS1 | c.1584C>T p.C528= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as rs759222500; called by muse, mutect2, varscan2
- FZD8 | c.1498C>T p.L500= | Silent (SNP) | VAF 54/229 reads (24%) | catalogued as COSV65967518; called by muse, mutect2, varscan2
- GPR153 | c.879G>T p.L293= | Silent (SNP) | VAF 43/230 reads (19%) | catalogued as COSV64938598; called by muse, mutect2, varscan2
- GRM7 | c.459G>T p.V153= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV63129718; called by muse, mutect2, varscan2
- H1-4 | c.219G>A p.V73= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs772592342, COSV56799840; called by muse, mutect2, varscan2
- HSF2 | c.57G>A p.E19= | Silent (SNP) | VAF 121/261 reads (46%) | catalogued as COSV63773387; called by muse, mutect2, varscan2
- KCND1 | c.948C>G p.G316= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- KRT9 | c.1455T>C p.Y485= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs148711206; called by muse, mutect2, varscan2
- MACF1 | c.5724A>G p.A1908= | Silent (SNP) | VAF 63/155 reads (41%) | called by muse, mutect2, varscan2
- MUC16 | c.19851C>A p.P6617= | Silent (SNP) | VAF 110/170 reads (65%) | catalogued as rs577291697, COSV67445475; called by muse, mutect2, varscan2
- MUC17 | c.4506C>T p.T1502= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100071617, COSV60280305; called by muse, mutect2, varscan2
- NLRP10 | c.696C>G p.A232= | Silent (SNP) | VAF 65/165 reads (39%) | catalogued as COSV100149464, COSV60778702; called by muse, mutect2, varscan2
- NLRP5 | c.2034C>T p.A678= | Silent (SNP) | VAF 46/329 reads (14%) | called by muse, mutect2, varscan2
- NOS1 | c.615G>T p.L205= | Silent (SNP) | VAF 130/233 reads (56%) | catalogued as COSV57606885; called by muse, mutect2, varscan2
- NOX5 | c.1230T>G p.L410= | Silent (SNP) | VAF 59/158 reads (37%) | called by muse, mutect2, varscan2
- NPR2 | c.688C>T p.L230= | Silent (SNP) | VAF 174/624 reads (28%) | catalogued as COSV61309229; called by muse, mutect2, varscan2
- NRXN2 | c.4131G>T p.T1377= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as COSV55447259, COSV55454374; called by muse, mutect2, varscan2
- NUP210 | c.3825G>T p.S1275= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV54402387, COSV54414325; called by muse, mutect2, varscan2
- OR14C36 | c.675G>A p.G225= | Silent (SNP) | VAF 26/394 reads (7%) | called by muse, mutect2
- OR2AK2 | c.819G>A p.A273= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs764697677, COSV100823802, COSV63559112; called by muse, mutect2, varscan2
- OTOP2 | c.846C>A p.V282= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV58880662; called by muse, mutect2, varscan2
- PCDHB9 | c.1902C>T p.D634= | Silent (SNP) | VAF 416/981 reads (42%) | catalogued as rs1222846756, COSV53381521, COSV53382219; called by muse, mutect2, varscan2
- PCDHGB4 | c.1854G>T p.G618= | Silent (SNP) | VAF 50/190 reads (26%) | called by muse, mutect2, varscan2
- PRDM9 | c.2601G>T p.R867= | Silent (SNP) | VAF 174/729 reads (24%) | catalogued as COSV57002630, COSV57007676; called by muse, mutect2, varscan2
- PRSS16 | c.699G>C p.A233= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV57914844; called by muse, mutect2, varscan2
- PTPN14 | c.108G>T p.T36= | Silent (SNP) | VAF 38/345 reads (11%) | catalogued as COSV65281062; called by muse, mutect2, varscan2
- RALGAPA2 | c.1695G>A p.Q565= | Silent (SNP) | VAF 87/272 reads (32%) | catalogued as COSV52488361; called by muse, mutect2, varscan2
- SLC25A17 | c.438C>T p.Y146= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV54350490; called by muse, mutect2, varscan2
- SLC28A3 | c.1191A>G p.A397= | Silent (SNP) | VAF 79/575 reads (14%) | catalogued as rs1482554113; called by muse, mutect2, varscan2
- TIAM1 | c.870C>G p.P290= | Silent (SNP) | VAF 78/298 reads (26%) | catalogued as COSV54538052; called by muse, mutect2, varscan2
- TXNL1 | c.168C>T p.F56= | Silent (SNP) | VAF 82/165 reads (50%) | catalogued as COSV54178252; called by muse, mutect2, varscan2
- UBASH3A | c.1017C>G p.A339= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as COSV52310546; called by muse, mutect2, varscan2
- VAV2 | c.2088G>T p.L696= (on ENST00000371850 / NM_001134398.2; = p.L686= on NM_003371.4) | Silent (SNP) | VAF 100/300 reads (33%) | catalogued as COSV64080170; called by muse, mutect2, varscan2
- VWA5B1 | c.90C>A p.G30= | Silent (SNP) | VAF 54/117 reads (46%) | catalogued as COSV57050384; called by muse, mutect2, varscan2
- ZIC4 | c.4A>C p.R2= | Silent (SNP) | VAF 86/316 reads (27%) | catalogued as COSV67170683; called by muse, mutect2, varscan2
- ZNF229 | c.57C>A p.A19= | Silent (SNP) | VAF 133/467 reads (28%) | catalogued as COSV52159693; called by muse, mutect2, varscan2
- AC022182.1 | n.671G>A | RNA (SNP) | VAF 80/238 reads (34%) | called by muse, varscan2
- ACBD5 | chr10:27195945 C>G | 3'Flank (SNP) | VAF 10/92 reads (11%) | catalogued as rs1475586677; called by muse, mutect2
- ACTG2 | c.256-328A>T | Intron (SNP) | VAF 87/256 reads (34%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824638 del T | 5'Flank (DEL) | VAF 92/159 reads (58%) | called by mutect2, pindel, varscan2
- ANKRD20A8P | n.1368C>A | RNA (SNP) | VAF 106/657 reads (16%) | called by muse, mutect2, varscan2
- BNIP2 | chr15:59689381 G>T | 5'Flank (SNP) | VAF 33/103 reads (32%) | catalogued as COSV51105095; called by muse, mutect2, varscan2
- CAVIN4 | c.*51G>C | 3'UTR (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- CUX1 | chr7:101815987 del C | 5'Flank (DEL) | VAF 125/400 reads (31%) | called by mutect2, pindel, varscan2
- CYS1 | chr2:10083857 A>T | 5'Flank (SNP) | VAF 76/300 reads (25%) | called by muse, mutect2, varscan2
- DRD2 | c.811-456T>A | Intron (SNP) | VAF 77/188 reads (41%) | called by muse, mutect2, varscan2
- FKBP7 | c.374-3286G>A | Intron (SNP) | VAF 71/408 reads (17%) | called by muse, mutect2, varscan2
- HNRNPA3 | c.740-12G>T | Intron (SNP) | VAF 86/329 reads (26%) | called by muse, mutect2, varscan2
- LMNTD1 | c.26+135A>G | Intron (SNP) | VAF 18/359 reads (5%) | called by muse, mutect2
- LYZL2 | c.*34G>T | 3'UTR (SNP) | VAF 103/314 reads (33%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-5750G>A | Intron (SNP) | VAF 190/573 reads (33%) | catalogued as rs1370337661; called by muse, mutect2, varscan2
- MKLN1 | c.2086+47G>A | Intron (SNP) | VAF 85/250 reads (34%) | called by muse, mutect2, varscan2
- NHLRC2 | c.*6616C>T | 3'UTR (SNP) | VAF 146/458 reads (32%) | catalogued as rs747427238; called by muse, mutect2, varscan2
- PARP6 | c.*187G>A | 3'UTR (SNP) | VAF 61/269 reads (23%) | catalogued as rs1433995090; called by muse, mutect2, varscan2
- PRAME | chr22:22563754 G>T | 5'Flank (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- PRKCB | c.1066-2876A>C | Intron (SNP) | VAF 45/154 reads (29%) | catalogued as rs1487720246; called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 26/614 reads (4%) | catalogued as rs910081914; called by muse, mutect2
- RPL13A | chr19:49487534 T>A | 5'Flank (SNP) | VAF 42/144 reads (29%) | called by muse, mutect2, varscan2
- SNHG10 | chr14:95517189 A>G | 3'Flank (SNP) | VAF 62/170 reads (36%) | called by muse, mutect2, varscan2
- SNRPN | chr15:24979947 G>T | 3'Flank (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2
- SSPOP | n.2503G>C | RNA (SNP) | VAF 18/61 reads (30%) | catalogued as COSV50486444; called by muse, varscan2
- TBX2 | chr17:61412271 G>T | 3'Flank (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- TBXT | c.*35C>G | 3'UTR (SNP) | VAF 136/270 reads (50%) | called by muse, mutect2, varscan2
- TNPO3 | c.1359-70A>G | Intron (SNP) | VAF 52/154 reads (34%) | called by muse, mutect2, varscan2
- VPS35 | c.102+37G>A | Intron (SNP) | VAF 73/322 reads (23%) | catalogued as rs1396203307; called by muse, mutect2, varscan2
